Somatic mutation profile of tumor specimen ALCH-B0A9-TTP1-A (aliquot ALCH-B0A9-TTP1-A-2-0-D-A694-36) from ALCHEMIST case ALCH-B0A9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,934 days).
Specimen ALCH-B0A9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89b460f6-4e7f-4b14-a630-d0ae57dd258d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0A9-NB1-A (Blood Derived Normal), aliquot ALCH-B0A9-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6e80835-b1ff-4005-aabd-cd5781eb3fc3

The open-access MAF lists 234 somatic variants for this specimen: 166 protein-altering or splice-affecting, 46 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 46, Intron 9, RNA 9, Nonsense Mutation 8, Splice Site 3, 3'UTR 2, Splice Region 2, 5'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 46/369 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 47/371 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANO2 | c.2608G>C p.E870Q (on ENST00000356134 / NM_001278597.3; = p.E874Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV59021479; called by muse, mutect2
- BRD2 | c.22C>G p.H8D | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.227); catalogued as rs377684930, COSV100875781; called by muse, mutect2, varscan2
- CCN3 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs141834767, COSV99422738; called by muse, mutect2
- COL1A2 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM062541, COSV99801741; called by muse, mutect2
- CPZ | c.823C>A p.R275S (on ENST00000360986 / NM_001014447.3; = p.R264S on NM_003652.3) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs140850654; called by muse, mutect2, varscan2
- CR1 | c.4955C>A p.P1652Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.966); catalogued as COSV65457546; called by muse, mutect2
- FAM83H | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1355152525; called by muse, mutect2, varscan2
- FAT2 | c.4660C>A p.R1554S | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55831366; called by muse, mutect2, varscan2
- FOXF2 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV99452938; called by muse, mutect2, varscan2
- FSIP1 | c.1602G>T p.R534S | Missense Mutation (SNP) | VAF 30/393 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1320253301; called by muse, mutect2
- GLG1 | c.3332G>T p.R1111L | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV52667620; called by muse, mutect2
- GLG1 | c.2249G>T p.R750L | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV52671504, COSV99215854; called by muse, mutect2
- HHAT | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54802868; called by muse, mutect2, varscan2
- HTR2C | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52200463; called by muse, mutect2
- HTR7 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53291025; called by muse, mutect2, varscan2
- HTT | c.2011G>A p.G671R | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487889724; called by muse, mutect2
- ILF3 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.299); catalogued as COSV99139273; called by muse, mutect2
- LAMA1 | c.7892G>T p.G2631V | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as COSV67532576; called by muse, mutect2
- MNDA | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100933330; called by muse, mutect2
- NRDE2 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1384873158, COSV62962499; called by muse, mutect2
- OR4A15 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1238905074, COSV100123896; called by muse, mutect2, varscan2
- OR5D16 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781145056; called by muse, mutect2
- OR5L2 | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV65723733; called by muse, mutect2
- OR6Y1 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100225532; called by muse, mutect2, varscan2
- PARP10 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV57300085; called by muse, mutect2
- PCDHB11 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.927); catalogued as rs1320678812; called by muse, mutect2
- PDGFRA | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV57268817, COSV57271168, COSV99957163; called by muse, mutect2, varscan2
- POTEE | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs1457198712, COSV100388716; called by muse, mutect2
- PPP4R1 | c.955A>G p.I319V (on ENST00000400556 / NM_001042388.3; = p.I302V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs1459107009; called by muse, mutect2
- RCOR3 | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1319506950; called by muse, mutect2, varscan2
- RYR2 | c.2116T>C p.Y706H | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63718936; called by muse, mutect2, varscan2
- RYR3 | c.7646C>A p.S2549Y (on ENST00000389232; = p.S2550Y on NM_001036.6) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101215169; called by muse, mutect2
- SCG2 | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 32/334 reads (10%) | catalogued as COSV59540615; called by muse, mutect2, varscan2
- SLC45A2 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1350569256; called by muse, mutect2
- SNCAIP | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160951140; called by muse, mutect2
- SON | c.5408G>A p.S1803N | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs779267364, COSV51666993; called by muse, mutect2
- SPECC1 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs144644210; called by muse, mutect2
- SRGAP3 | c.2939G>T p.R980M | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64530819; called by muse, mutect2, varscan2
- STYXL2 | c.2210A>G p.Q737R | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99608982; called by muse, mutect2, varscan2
- TCEAL4 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 18/202 reads (9%) | catalogued as COSV101010267; called by muse, mutect2
- TCIRG1 | c.501C>T p.V167= | Splice Region (SNP) | VAF 8/76 reads (11%) | catalogued as rs1404955903; called by muse, mutect2, varscan2
- TNR | c.523T>A p.C175S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV54905742; called by muse, mutect2
- TPH2 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61593559; called by muse, mutect2
- USH2A | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 42/515 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.148); catalogued as rs752682771, COSV100232717, COSV56448781; called by muse, mutect2
- WDR87 | c.6192G>C p.E2064D | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.669); catalogued as COSV58192665; called by muse, mutect2
- ZBED5 | c.1790A>T p.D597V | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV69721478; called by muse, mutect2
- ZEB2 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57959641; called by muse, mutect2
- ZNF334 | c.1415A>G p.H472R | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs139473216; called by muse, mutect2, varscan2
- ZNF564 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV59435406; called by muse, mutect2
- ZNF729 | c.2347C>T p.L783F | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1324143552; called by muse, mutect2
- ZNF730 | c.851A>T p.Y284F | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV74168321; called by muse, mutect2
- ZNF823 | c.460C>T p.H154Y (on ENST00000341191 / NM_001297610.2; = p.H110Y on NM_017507.2) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV57875373; called by muse, mutect2
- ZZEF1 | c.6280G>T p.A2094S | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); catalogued as COSV67560083; called by muse, mutect2, varscan2
- ABCA10 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ADAMTS20 | c.1329G>C p.W443C | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADGB | c.4819-1G>T p.X1607_splice | Splice Site (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- ALG10 | c.953T>C p.L318S | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMHR2 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANK2 | c.11017C>A p.L3673M | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- APBA2 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGAP10 | c.853A>T p.S285C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- B3GALT2 | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BFSP1 | c.1132A>T p.T378S | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1A | c.2507A>G p.N836S | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); called by muse, mutect2
- CALHM6 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); called by muse, mutect2
- CBLIF | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 52/508 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCT6A | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2
- CDYL | c.1164G>T p.K388N (on ENST00000328908 / NM_001368125.1; = p.K334N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CHRNB3 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIR1 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- CLTC | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- CNKSR2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- CNTNAP2 | c.396T>A p.N132K | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2
- COL11A1 | c.2305G>A p.G769S | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL6A3 | c.6879+1G>C p.X2293_splice | Splice Site (SNP) | VAF 21/245 reads (9%) | called by muse, mutect2
- CPEB3 | c.896A>C p.N299T | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2
- CPSF3 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- CRYGC | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- CTBP2 | c.327C>G p.D109E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- CTLA4 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.037); called by muse, mutect2
- CUL4B | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); called by muse, mutect2
- DAO | c.932A>T p.H311L | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK11 | c.5496T>A p.H1832Q | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2
- DROSHA | c.82A>T p.R28* | Nonsense Mutation (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- EDEM1 | c.1905G>T p.E635D | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- ELK3 | c.1222T>G p.*408Gext*1 | Nonstop Mutation (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- FGF7 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 33/370 reads (9%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.702); called by muse, mutect2
- FSHR | c.983T>A p.M328K | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.091); called by muse, mutect2
- FSTL5 | c.1327T>C p.W443R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABRP | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.138); called by muse, mutect2
- GAK | c.2054A>G p.K685R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- GCN1 | c.6443G>T p.G2148V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GDI2 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- GHR | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GLDC | c.1135A>G p.S379G | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPIHBP1 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR83 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2
- GRID1 | c.2761C>A p.Q921K | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.025); called by muse, mutect2
- HAVCR1 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCN4 | c.2144-2A>C p.X715_splice | Splice Site (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- HCN4 | c.1232T>A p.L411Q | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMCN1 | c.12023C>A p.P4008Q | Missense Mutation (SNP) | VAF 24/479 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0100 | c.150T>A p.F50L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMA1 | c.6267G>T p.K2089N | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- LATS2 | c.1750A>T p.S584C | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2
- LIPG | c.40T>A p.C14S | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- LPCAT1 | c.609A>T p.I203= | Splice Region (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- LRRC37A3 | c.4201G>A p.V1401I | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAT4D | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MTNR1A | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- MTUS2 | c.1426G>T p.V476F | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.42); called by muse, mutect2
- MUC1 | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MUC5B | c.6064G>T p.V2022L | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- MYPN | c.2305T>C p.S769P | Missense Mutation (SNP) | VAF 27/386 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- NAT8 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLGN4X | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0.141); called by muse, mutect2
- NLRP2 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- NRG3 | c.1038G>T p.L346F | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- NUP155 | c.599T>A p.L200* (on ENST00000231498 / NM_153485.3; = p.L141* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- OR1L3 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OR2J3 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); called by muse, mutect2
- OR2M4 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- OVCH1 | c.1976T>C p.L659P | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.063); called by muse, mutect2
- PCDH11X | c.2596A>G p.M866V | Missense Mutation (SNP) | VAF 45/497 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- PDAP1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PDCL2 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- PGGT1B | c.765G>T p.R255S | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3C2G | c.3494G>T p.G1165V (on ENST00000676171; = p.G1124V on NM_004570.5) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLA2G4D | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- PLAC8 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCH1 | c.2659G>T p.G887C (on ENST00000340059 / NM_001130960.2; = p.G879C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNA4 | c.644C>A p.A215E | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PREX1 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- PSAP | c.1435A>G p.I479V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2
- PTPRG | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2
- RAB44 | c.152T>A p.F51Y | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB44 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM27 | c.1544G>C p.R515P | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.268); called by muse, mutect2
- RGPD4 | c.5056C>A p.Q1686K | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- RP1 | c.5185A>T p.S1729C | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2
- SCN3A | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 66/698 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- SEMA3F | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SEMA4D | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); called by muse, mutect2
- SFRP1 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIRPD | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, varscan2
- SLC18A1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SP2 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); called by muse, mutect2
- SPHKAP | c.780C>A p.N260K | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAS2R38 | c.730A>T p.K244* | Nonsense Mutation (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- TBC1D9B | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.314); called by muse, mutect2
- TDP1 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- TMCC2 | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- TRIM58 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- TRIM9 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2
- TTC8 | c.695C>T p.S232F (on ENST00000338104 / NM_001288781.1; = p.S216F on NM_144596.4) | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2
- TTN | c.91054A>G p.M30352V (on ENST00000591111; = p.M22928V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/146 reads (5%) | PolyPhen benign (0); called by muse, mutect2
- WDHD1 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2
- WDR87 | c.5671G>T p.V1891L | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZFHX4 | c.2821G>T p.D941Y | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF543 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF606 | c.626G>T p.S209I | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2
- ZNF727 | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF875 | c.767A>T p.K256M | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); called by muse, mutect2
- ZNF879 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- ABCA1 | c.1488G>T p.R496= | Silent (SNP) | VAF 37/445 reads (8%) | called by muse, mutect2
- ABL1 | c.3201C>T p.C1067= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs775721460; called by muse, mutect2, varscan2
- ANK3 | c.7620A>T p.T2540= | Silent (SNP) | VAF 16/175 reads (9%) | called by muse, mutect2
- ARID3B | c.243G>T p.V81= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ART5 | c.396C>A p.A132= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- BBX | c.768C>T p.S256= | Silent (SNP) | VAF 7/198 reads (4%) | called by muse, mutect2
- CCN3 | c.681G>T p.R227= | Silent (SNP) | VAF 28/458 reads (6%) | catalogued as rs1159957552; called by muse, mutect2
- CD79B | c.303C>T p.N101= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs115494685; ClinVar: likely benign; called by muse, mutect2
- CDHR2 | c.1269A>T p.A423= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, varscan2
- CSAD | c.1059G>A p.V353= (on ENST00000444623 / NM_001244705.2; = p.V380= on NM_015989.5) | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- DDB1 | c.3099C>T p.V1033= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs1345192845; called by muse, mutect2
- DTD2 | c.387A>G p.E129= | Silent (SNP) | VAF 12/313 reads (4%) | called by muse, mutect2
- ECM2 | c.468C>A p.V156= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- EPO | c.117G>T p.L39= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- F2R | c.996C>T p.L332= | Silent (SNP) | VAF 23/454 reads (5%) | called by muse, mutect2
- FAM135B | c.2487G>T p.L829= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs753565189; called by muse, mutect2, varscan2
- FOXE1 | c.933G>T p.A311= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- FSHR | c.2040T>C p.S680= | Silent (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- GLDC | c.1134C>A p.T378= | Silent (SNP) | VAF 19/227 reads (8%) | catalogued as COSV100394585; called by muse, mutect2
- GLI2 | c.2040G>T p.L680= (on ENST00000361492 / NM_001374353.1; = p.L697= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV58034286; called by muse, varscan2
- GPAA1 | c.489G>T p.L163= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- GRIN2A | c.4326C>A p.P1442= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- HS1BP3 | c.153G>A p.A51= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs768112807; called by muse, mutect2
- MKKS | c.669A>G p.S223= | Silent (SNP) | VAF 19/262 reads (7%) | called by muse, mutect2
- MOSPD2 | c.1017A>C p.G339= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- OR10G4 | c.546C>A p.P182= | Silent (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- OR11G2 | c.759G>T p.V253= | Silent (SNP) | VAF 20/399 reads (5%) | called by muse, mutect2
- PCDHA2 | c.2263C>A p.R755= | Silent (SNP) | VAF 10/197 reads (5%) | called by muse, mutect2
- PCDHB14 | c.2034G>T p.P678= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- PDE4B | c.108G>A p.G36= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs762690777; called by muse, mutect2
- PLEC | c.12903C>T p.D4301= (on ENST00000322810 / NM_201380.4; = p.D4191= on NM_000445.5) | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
- PPP2R2B | c.297C>G p.P99= (on ENST00000394409; = p.P165= on NM_181674.2) | Silent (SNP) | VAF 9/230 reads (4%) | catalogued as COSV60757033; called by muse, mutect2
- PRRC2C | c.684A>T p.P228= (on ENST00000367742; = p.P226= on NM_015172.4) | Silent (SNP) | VAF 21/276 reads (8%) | called by muse, mutect2
- PTCHD4 | c.2013G>T p.V671= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- PTDSS1 | c.1191C>T p.L397= | Silent (SNP) | VAF 32/280 reads (11%) | called by muse, mutect2, varscan2
- RAG1 | c.1977C>T p.C659= | Silent (SNP) | VAF 16/382 reads (4%) | called by muse, mutect2
- RBM14 | c.714G>T p.R238= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- SLC12A2 | c.1326A>T p.L442= | Silent (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- SMG9 | c.1539A>T p.A513= | Silent (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- SORCS3 | c.195C>T p.A65= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TNR | c.393C>A p.A131= | Silent (SNP) | VAF 17/269 reads (6%) | called by muse, mutect2
- WDFY4 | c.7611C>A p.I2537= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as COSV55427105; called by muse, mutect2
- YLPM1 | c.6310C>T p.L2104= | Silent (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
- ZNF512B | c.2106G>T p.L702= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- ZNF823 | c.459A>T p.T153= (on ENST00000341191 / NM_001297610.2; = p.T109= on NM_017507.2) | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- ZNF879 | c.1020G>C p.G340= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ADAM21P1 | n.757A>G | RNA (SNP) | VAF 36/273 reads (13%) | called by muse, mutect2, varscan2
- AGTRAP | c.62+202C>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs1221020347; called by muse, mutect2
- BOC | c.667+280G>A | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- BOC | c.667+281G>A | Intron (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- CHORDC1 | c.64+232G>A | Intron (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- CSN1S2AP | n.368C>A | RNA (SNP) | VAF 37/353 reads (10%) | called by muse, mutect2, varscan2
- EML1 | c.68-595A>G | Intron (SNP) | VAF 21/257 reads (8%) | catalogued as rs774692093; called by muse, mutect2
- H3C8 | c.*10G>T | 3'UTR (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.252G>T | RNA (SNP) | VAF 33/372 reads (9%) | catalogued as rs761533544; called by muse, mutect2
- L1CAM | c.-109+2226G>A | Intron (SNP) | VAF 6/95 reads (6%) | catalogued as rs782581480; called by muse, mutect2
- MIR370 | n.44G>T | RNA (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- MIR517A | n.29C>A | RNA (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- NBPF22P | n.879C>A | RNA (SNP) | VAF 18/423 reads (4%) | called by muse, mutect2
- OR2L1P | n.905G>T | RNA (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- OR2L1P | n.906G>C | RNA (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- P4HTM | c.1074-11del | Intron (DEL) | VAF 3/31 reads (10%) | catalogued as rs760453324, COSV59086098; called by pindel, varscan2
- PCMTD1 | c.706+4135A>C | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2
- POTEF | c.*4G>T | 3'UTR (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3473A>T | Intron (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- TUBB7P | n.337A>T | RNA (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- WFDC8 | c.-17C>T | 5'UTR (SNP) | VAF 16/175 reads (9%) | called by muse, mutect2
- ZNF727 | c.-91T>G | 5'UTR (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
